Gene-level copy-number profile of tumor specimen TCGA-ES-A2HS-01A from TCGA case TCGA-ES-A2HS, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 80.1 years (29,268 days).
Specimen TCGA-ES-A2HS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.ebbd5627-a855-4eb0-88c5-90cd052a70ea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ES-A2HS-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d0114106-fa31-4d6f-9499-64836db1a1e0

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,127; copy number 3: 10,657; copy number 4: 17,400; copy number 5: 10,773; copy number 6: 16,614; copy number 7: 490; copy number 9: 213; copy number 10: 1,534; copy number 11: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ES-A2HS-01A-11D-A182-01): tumor purity 0.66, ploidy 4.44, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
